Somatic mutation profile of tumor specimen 0DQU4X from CCDI case PBCFND, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Dysembryoplastic neuroepithelial tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.0 years (5,100 days).
Specimen 0DQU4X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 187fbd00-c754-4fad-b56d-5dbb84d9d38e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQU5E (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fb4c07f-79a8-42d7-b462-2127d2257061

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.4922T>C p.I1641T (on ENST00000358273 / NM_001042492.3; = p.I1620T on NM_000267.3) | Missense Mutation (SNP) | VAF 39/432 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs1567611281, CM1512956; ClinVar: uncertain significance; called by muse, mutect2
- NF1 | c.6758G>A p.G2253E (on ENST00000358273 / NM_001042492.3; = p.G2232E on NM_000267.3) | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876659295, COSV62193824; ClinVar: uncertain significance; called by muse, mutect2
- OLFML2B | c.126C>T p.D42= | Silent (SNP) | VAF 19/590 reads (3%) | catalogued as rs1367588043; called by muse, mutect2
